Somatic mutation profile of tumor specimen MP2PRT-PATTSG-TMP1-A (aliquot MP2PRT-PATTSG-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATTSG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,468 days).
Specimen MP2PRT-PATTSG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eabc932c-8405-4c26-a050-620e1d547e2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATTSG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATTSG-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5df78ad-e4e6-464a-9df2-9a83758736b6

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBL1XR1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs1057517933, CM162314, COSV70501537; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IL2RB | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 134/276 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53427773; called by muse, mutect2
- PGR | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 106/225 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs371165895, COSV99677266; called by muse, mutect2, varscan2
- SLC17A8 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752771712, COSV60122167, COSV60125435; called by muse, mutect2, varscan2
- SLC7A13 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 201/457 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139761067; called by muse, mutect2, varscan2
- CEP97 | c.2462G>C p.S821T | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERG | c.777T>A p.Y259* (on ENST00000398919 / NM_001243428.1; = p.Y235* on NM_004449.4) | Nonsense Mutation (SNP) | VAF 155/444 reads (35%) | called by muse, mutect2, varscan2
- GAP43 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 188/444 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RHBDD3 | c.694A>C p.R232= | Splice Region (SNP) | VAF 166/393 reads (42%) | called by muse, mutect2, varscan2
- RYR2 | c.2823G>T p.K941N | Missense Mutation (SNP) | VAF 121/256 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- DUOX2 | c.2404C>T p.L802= | Silent (SNP) | VAF 256/538 reads (48%) | called by muse, mutect2, varscan2
